Surgical pathology report (de-identified scan), TCGA case TCGA-06-0127, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0127-01A (Primary Tumor).

06-0127

PATHOLOGICAL DIAGNOSIS:

A,B. BRAIN BIOPSY: GLIOBLASTOMA MULTIFORME. (MIB-1: 10%)

Operation/Specimen:

Clinical History and Pre-Op Dx:

GROSS PATHOLOGY:

A. Multiple 0.2-0.4 cm tissue fragments, all submitted #1,2.

INTRAOPERATIVE CONSULTATION DIAGNOSIS: Glioma.

B.

SPECIMEN: 2, parietal tumor.
FIXATIVE: Saline.
GENERAL: A 1.5 x 1.3 x 1.0 cm. aggregate of several fragments of
dusky red to gray-tan brain tissue.
SECTIONS: 3, all submitted.

MICROSCOPIC: A,B. Sections show a high grade glioma characterized by hypercellularity, cellular pleomorphism, mitotic activity, capillary proliferation and foci of palisading necrosis. These features are consistent with glioblastoma.

ADDENDUM REPORT:

MICROSCOPIC: MIB-1 stain shows that the proliferation index of the tumor cells is about 10%.

Source: NCI Genomic Data Commons file 181a9667-930d-4c86-8484-c9556eebbbfb (TCGA-06-0127.6C344BA6-E1E2-457D-A4DE-A03E03EE706B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).